Somatic mutation profile of tumor specimen 0DGFVV from CCDI case PBBTBL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 10.6 years (3,869 days).
Specimen 0DGFVV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d6850f9-fd19-4f62-a183-3b80ac84f374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGFTN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35647885-300c-4783-9a6b-a359c2876d16

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>C p.E1813A | Missense Mutation (SNP) | VAF 47/617 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2
- ASIC4 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100761649; called by muse, mutect2
- MGAT4C | c.295+1G>A p.X99_splice | Splice Site (SNP) | VAF 29/428 reads (7%) | catalogued as rs201052353, COSV59833403; called by muse, mutect2
- OR2J3 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 66/752 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs372756606; called by muse, mutect2
- RYR2 | c.13397A>T p.H4466L | Missense Mutation (SNP) | VAF 68/894 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.066); catalogued as COSV63669834; called by muse, mutect2
- TESK1 | c.1410C>G p.C470W | Missense Mutation (SNP) | VAF 46/700 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV52412531; called by muse, mutect2
- COBLL1 | c.967C>G p.L323V (on ENST00000392717; = p.L285V on NM_014900.5) | Missense Mutation (SNP) | VAF 60/840 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH11 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 44/794 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- GZF1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 62/946 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- NBEAL1 | c.3368C>A p.T1123N | Missense Mutation (SNP) | VAF 38/637 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- PTF1A | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.258); called by muse, mutect2
- ASIC4 | c.72G>A p.G24= | Silent (SNP) | VAF 14/333 reads (4%) | catalogued as rs1202894069; called by muse, mutect2
- TRPM5 | c.2370C>T p.D790= | Silent (SNP) | VAF 74/1166 reads (6%) | catalogued as rs370954631; called by muse, mutect2
